CPTAC case C3L-03589 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a4359891-3763-41c7-b973-7843952f03d8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 59.9 years (21,871 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 883 days (2.4 years); Days to last follow up: 883 days (2.4 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 0.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 427 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 883 days (2.4 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 129.73 kg; Height: 172.72 cm; BMI: 43.48; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking onset year: 1972; Tobacco smoking quit year: 2016; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 44.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03589-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 10 days; Initial weight: 697 mg; Time between clamping and freezing: 15 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03589-23: Section location: endometrium; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3L-03589-13: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 10 days; Time between clamping and freezing: 15 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-03589-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 10 days; Method of sample procurement: Blood Draw.
